Somatic mutation profile of tumor specimen BA3009D (aliquot aq-BA3009D) from BEATAML1.0 case 2213, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 26.6 years (9,706 days).
Specimen BA3009D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03db7ccd-ec77-48cd-acc3-06b4d386f1d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2002D (Solid Tissue Normal), aliquot aq-BA2002D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdba24de-6e09-41e6-83b2-d1b04054921a

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXN4 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs967226089, COSV54494368; called by muse, mutect2
- GTF3C3 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs779060025, COSV55832291; called by muse, varscan2
- LPIN2 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 112/253 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs757315664, COSV54425376; called by muse, mutect2, varscan2
- OR4X1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs764221173; called by muse, varscan2
- ACTL6B | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPAB | c.234C>A p.S78R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC9 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLMAP | c.1205C>T p.T402I (on ENST00000428312 / NM_001377924.1; = p.T423I on NM_007159.5) | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TACC2 | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPBGL | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- VARS1 | c.401C>G p.A134G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- KCNJ12 | c.78G>A p.S26= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as rs571676444, COSV100054821, COSV100056109; called by muse, mutect2, varscan2
- LAMC1 | c.1701C>A p.G567= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- PKD1L3 | c.2562G>A p.E854= | Silent (SNP) | VAF 58/69 reads (84%) | called by muse, mutect2, varscan2
- UGT1A6 | c.1407C>A p.G469= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV59391760, COSV59394258; called by mutect2, varscan2
- BBS2 | c.1397+46G>T | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- DEPDC5 | c.695-50T>C | Intron (SNP) | VAF 11/80 reads (14%) | catalogued as rs1299447316; called by muse, mutect2, varscan2
- KCNMB4 | c.465-7730C>T | Intron (SNP) | VAF 45/123 reads (37%) | catalogued as rs1387532127, COSV50692841; called by muse, mutect2, varscan2
